Somatic mutation profile of tumor specimen PCProject_0177_T1_WES (aliquot PCProject_0177_T1_WES_1) from CMI case PCProject_0177, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 49.0 years (17,899 days).
Specimen PCProject_0177_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1164d6ca-0523-48b3-8a47-cfd0c9e6079e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0177_SALIVA (Saliva), aliquot PCProject_0177_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/459549cd-9e53-4737-b8d3-648f1ad69884

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Frame Shift Del 3, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+1G>A p.X307_splice | Splice Site (SNP) | VAF 111/595 reads (19%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRL1 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.608); catalogued as rs202034157; called by muse, mutect2, varscan2
- CACNB2 | c.1823G>A p.R608H (on ENST00000324631 / NM_201596.3; = p.R553H on NM_000724.4) | Missense Mutation (SNP) | VAF 66/369 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); catalogued as rs771011929, COSV56644129; called by muse, mutect2, varscan2
- CAT | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 177/1104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757901578, COSV53813381; called by muse, varscan2
- CSMD3 | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 63/395 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1276722271; called by muse, mutect2, varscan2
- DENND2B | c.2645G>A p.S882N | Missense Mutation (SNP) | VAF 48/318 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs148817707; called by muse, mutect2, varscan2
- FTMT | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.551); catalogued as rs1400684823, COSV58419742; called by muse, mutect2, varscan2
- METTL22 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 38/313 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs752069924; called by muse, mutect2, varscan2
- PAX7 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 55/305 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.988); catalogued as rs189558094; called by muse, mutect2, varscan2
- UBASH3A | c.1735G>T p.D579Y | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs375755307; called by muse, mutect2, varscan2
- ADRA1B | c.1326_1339del p.C442Wfs*14 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | called by mutect2, pindel*
- CCDC146 | c.2764C>G p.P922A | Missense Mutation (SNP) | VAF 70/488 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHRS4 | c.65C>A p.S22Y | Missense Mutation (SNP) | VAF 46/469 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- FBXO31 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYDIN | c.9277A>G p.T3093A | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL10RB | c.801del p.E268Sfs*28 | Frame Shift Del (DEL) | VAF 82/717 reads (11%) | called by mutect2, pindel, varscan2
- KLK2 | c.581_582del p.E194Vfs*12 | Frame Shift Del (DEL) | VAF 52/298 reads (17%) | called by pindel, varscan2
- PCDH18 | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); called by muse, mutect2
- SOX17 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAT3 | c.1274A>T p.N425I | Missense Mutation (SNP) | VAF 105/856 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NUMB | c.588T>A p.R196= (on ENST00000355058; = p.R185= on NM_003744.5) | Silent (SNP) | VAF 18/586 reads (3%) | called by muse, mutect2
- RPL3L | c.657C>A p.V219= | Silent (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- RPL3L | c.549C>T p.I183= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV51906745; called by muse, varscan2
- TMEM182 | c.141C>T p.N47= | Silent (SNP) | VAF 25/176 reads (14%) | catalogued as rs540932130, COSV68425405; called by muse, mutect2, varscan2
- VIL1 | c.1572C>T p.G524= | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as rs140919034; called by muse, mutect2, varscan2
- IRF2 | c.529+929C>A | Intron (SNP) | VAF 53/403 reads (13%) | called by muse, mutect2, varscan2
